Somatic mutation profile of tumor specimen BA2817D (aliquot aq-BA2817D) from BEATAML1.0 case 2557, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.5 years (26,832 days).
Specimen BA2817D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f097791-e6c3-433f-b015-e6e4bb8e926c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2562D (Solid Tissue Normal), aliquot aq-BA2562D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/161e1826-08b8-4c53-8245-fd3bedf09d43

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MFF | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs748723518; called by mutect2, varscan2
- CCDC40 | c.3094G>C p.E1032Q | Missense Mutation (SNP) | VAF 12/313 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.159); called by muse, mutect2
- DEAF1 | c.1001C>G p.T334S | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); called by mutect2, varscan2
- NHS | c.2534A>T p.D845V | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRLR | c.1306G>C p.V436L | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- CCDC39 | c.2733C>T p.F911= | Silent (SNP) | VAF 29/226 reads (13%) | called by muse, mutect2, varscan2
- CHRM4 | c.1089G>T p.T363= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs1043247515, COSV59182968; called by muse, mutect2
- HMCN2 | c.4110C>G p.G1370= | Silent (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2
- ERBB2 | c.1021+39G>C | Intron (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2
- PPIE | c.*14C>A | 3'UTR (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
